Somatic mutation profile of tumor specimen MMRF_1355_3_BM_CD138pos (aliquot MMRF_1355_3_BM_CD138pos_T1_KBS5U_L06437) from MMRF case MMRF_1355, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.0 years (27,387 days).
Specimen MMRF_1355_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11da2806-18bc-425f-bf10-7535159d0c96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1355_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1355_2_PB_Whole_C1_KAS5U_L01938; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2475cb6b-1c77-4b32-be75-9264a3a31e03

The open-access MAF lists 16 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 4, Missense Mutation 4, Silent 3, Intron 2, Nonsense Mutation 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPNE8 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs926258147, COSV58838522; called by muse, mutect2
- LTB | c.163-8C>G | Splice Region (SNP) | VAF 16/359 reads (4%) | catalogued as rs767488608, COSV53001079; called by muse, mutect2
- STOX2 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1250261800, COSV57855444; called by muse, mutect2
- AJM1 | c.2734T>C p.F912L | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- BCL6 | c.1966A>T p.K656* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- COL9A1 | c.1745A>T p.K582M | Missense Mutation (SNP) | VAF 9/223 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MPHOSPH8 | c.1863C>T p.I621= | Silent (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- NOTCH3 | c.5247G>A p.Q1749= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- TCEAL1 | c.42C>T p.S14= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as rs1233498477; called by muse, mutect2
- BCL7A | chr12:122021134 G>A | 5'Flank (SNP) | VAF 6/164 reads (4%) | catalogued as rs895189444; called by muse, mutect2
- CBLB | c.*1038A>G | 3'UTR (SNP) | VAF 4/97 reads (4%) | called by muse, mutect2
- GFRA2 | c.*54G>A | 3'UTR (SNP) | VAF 6/121 reads (5%) | catalogued as rs1293939443; called by muse, mutect2
- L1CAM | c.3458-69C>T | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- MAN2C1 | c.1219-31C>T | Intron (SNP) | VAF 8/67 reads (12%) | catalogued as rs763222258; called by muse, mutect2
- PIAS1 | c.*2817_*2820del | 3'UTR (DEL) | VAF 4/38 reads (11%) | catalogued as rs1482905395; called by mutect2, pindel, varscan2
- TNFRSF1B | c.*1134C>T | 3'UTR (SNP) | VAF 12/347 reads (3%) | called by muse, mutect2
